CCDI case PBCCFU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/b2d3f7c0-1ec6-4470-aa9e-ea0a5ec157d7

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Teratoma, malignant, NOS: ICD-O-3 morphology code: 9080/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 11.7 years (4,275 days).

Biospecimens (3 samples)
- Sample 0DOA27: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOA2Y: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOA3R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
